Gene-level copy-number profile of tumor specimen TCGA-A6-6648-01A from TCGA case TCGA-A6-6648, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 56.5 years (20,641 days).
Specimen TCGA-A6-6648-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.f591dd35-df1e-4b21-a2b2-7d986b117a33.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-6648-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/233c1199-8073-43dd-a83b-d683783a9b7a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 816; copy number 2: 12,777; copy number 3: 28,171; copy number 4: 13,100; copy number 5: 3,990; copy number 6: 45; copy number 9: 910; copy number 12: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-6648-01A-11D-1770-01): tumor purity 0.46, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,884,250–14,935,363, 2 genes (within-gene range 0–2): MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 915 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:33,604,856–35,796,550, 16 genes, copy number 9–12 (within-gene range 5–12): AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1.
- chr20:30,214,765–64,313,132, 899 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 807. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
